Surgical pathology report (de-identified scan), TCGA case TCGA-GS-A9U4, project TCGA-DLBC (Lymphoid Neoplasm Diffuse Large B-cell Lymphoma), tissue source site Fundacio Clinic per a la Recerca Biomedica, specimen TCGA-GS-A9U4-01A (Primary Tumor).

SUBMAXILAR RIGHT ADENOPATY:

A pinky tissue fragment of 4,2 x 2,5 x 0,5 cm in which a lymph node of 3 cm is identified. It presents geographic necrotic areas.

LYMPH NODE, RIGHT SUBMAXILAR REGION (EXCISION):

- DIFFUSE LARGE B-CELL LYMPHOMA, CD20 POSITIVE ASSOCIATED WITH EPSTEIN-BARR VIRUS INFECTION

Sections show a lymph node with total replacement of the architecture due to the presence of a diffuse infiltration of atypical lymphoid proliferation, composed of medium to large cells, anaplastic, some multinucleate, with prominent nucleoli and basophilic cytoplasm. This neoplastic infiltration is associated with extents areas of necrosis and fibrosis. The tumor shows an angiocentric growth pattern.

The tumor cells are positive for CD20, CD79a, OCT-2, BOB.1, BCL2, MUM1, LMP1 and CD30, and are negative for CD10, BCL6, CD15, ALK1, CD3, CD4, CD5, CD7 and CD8. The in situ hybridization for the RNA of the Epstein-Barr virus (EBER) is positive. The Ki67 proliferative index is high (70%).

PCR IGH FR3: Monoclonal
PCR TCR gamma: Polyclonal

ICD-O-3
Lymphoma, diffuse large B-cell NOS
Site ^{CLL} Lymph node, submandibular 9680/3
^{path} Lymph node, submaxillary C77.0
908/31/14

Source: NCI Genomic Data Commons file c49923f8-459b-4b02-8ccb-58013c7eb1e6 (TCGA-GS-A9U4.599B4A65-9372-43BC-9236-0C49CD264979.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).